Somatic mutation profile of tumor specimen 0DEP10 from CCDI case PBBRBS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 14.1 years (5,156 days).
Specimen 0DEP10: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50f48e5d-cb08-4d44-9939-580aa05791af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEP1E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f474b70c-7fba-42c5-89a5-4e7fbb27ff26

The open-access MAF lists 14 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLCO1B1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 182/633 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as rs1410898997; called by muse, mutect2, varscan2
- TAS1R2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs771595070, COSV64747276; called by muse, mutect2, varscan2
- CACNA2D1 | c.1907A>T p.E636V (on ENST00000356253 / NM_001366867.1; = p.E617V on NM_000722.4) | Missense Mutation (SNP) | VAF 313/974 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, varscan2
- DNAH6 | c.5515G>A p.G1839R | Missense Mutation (SNP) | VAF 105/505 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARVA | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 88/908 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2
- TPTE | c.650A>G p.K217R (on ENST00000618007 / NM_199261.4; = p.K199R on NM_199259.4) | Missense Mutation (SNP) | VAF 276/1397 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, varscan2
- CDHR3 | c.2136G>A p.V712= | Silent (SNP) | VAF 40/749 reads (5%) | catalogued as rs1290364451; called by muse, mutect2
- SERPINA10 | c.684C>A p.T228= | Silent (SNP) | VAF 40/545 reads (7%) | called by muse, mutect2
- TEX15 | c.7098C>T p.S2366= (on ENST00000256246; = p.S2749= on NM_001350162.2) | Silent (SNP) | VAF 41/669 reads (6%) | catalogued as rs772422409, COSV56341688, COSV56343652; called by muse, mutect2
- VCX3B | c.594C>T p.S198= | Silent (SNP) | VAF 202/708 reads (29%) | catalogued as rs1569240276; called by muse, mutect2, varscan2
- CPNE8 | c.799-1691del | Intron (DEL) | VAF 24/92 reads (26%) | called by mutect2, varscan2
- MINK1 | c.2564+23C>T | Intron (SNP) | VAF 47/264 reads (18%) | catalogued as rs745871853; called by muse, mutect2, varscan2
- NUDCD2 | c.-4G>A | 5'UTR (SNP) | VAF 26/702 reads (4%) | called by muse, mutect2
- ZFYVE19 | c.-328C>A | 5'UTR (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
